Gene-level copy-number profile of tumor specimen TCGA-55-1596-01A from TCGA case TCGA-55-1596, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.8 years (20,381 days).
Specimen TCGA-55-1596-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.20c2ec93-b775-47e9-aeaf-4e5e9d9de1fe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-1596-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9bd0c600-fe56-4427-8bf7-192f59766f11

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 233; copy number 2: 17,667; copy number 3: 11,228; copy number 4: 21,695; copy number 5: 4,828; copy number 6: 2,411; copy number 7: 1,252; copy number 8: 45; copy number 9: 234; copy number 16: 129; copy number 20: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-1596-01A-01D-0944-01): tumor purity 0.63, ploidy 3.42, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 457 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:31,805,398–32,446,061, 19 genes, copy number 9: ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P, AL391839.3.
- chr17:37,977,972–45,372,057, 438 genes, copy number 9–20 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 233. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
